FM case AD9492 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026).
https://portal.gdc.cancer.gov/cases/e65a0858-5e5f-4493-a637-42ec5ed7fb59

Female, 60.1 years: diagnosis not reported by GDC; metastasis biopsied or resected from the vertebral column. Tumor nuclei on the sequenced sample's slide: 40% (pathologist estimate recorded by GDC). Sample type: Metastatic.
